Somatic mutation profile of tumor specimen TCGA-KK-A6E2-01A (aliquot TCGA-KK-A6E2-01A-11D-A30X-08) from TCGA case TCGA-KK-A6E2, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Prostate gland; Age at diagnosis: 54.7 years (19,974 days).
Specimen TCGA-KK-A6E2-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 71a041bf-bf5d-472e-8eb5-1c7c3e6b5960.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-KK-A6E2-11A (Solid Tissue Normal), aliquot TCGA-KK-A6E2-11A-21D-A30X-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/773c8e04-1989-4785-b0a7-9df35e28befa

The open-access MAF lists 37 somatic variants for this specimen: 26 protein-altering or splice-affecting, 10 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 22, Silent 10, Nonsense Mutation 3, Frame Shift Ins 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACAA2 | c.1105T>G p.L369V | Missense Mutation (SNP) | VAF 5/83 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV53270073; called by muse, mutect2
- ARHGEF1 | c.160C>T p.R54W | Missense Mutation (SNP) | VAF 29/70 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.75); catalogued as rs782110668, COSV61526536; called by muse, mutect2, varscan2
- CIAPIN1 | c.451A>T p.S151C | Missense Mutation (SNP) | VAF 16/124 reads (13%) | SIFT tolerated (0.08); PolyPhen benign (0.381); catalogued as COSV67953231; called by muse, mutect2, varscan2
- CYP4F12 | c.821G>A p.R274Q | Missense Mutation (SNP) | VAF 36/136 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.743); catalogued as rs781561176, COSV61172664; called by muse, mutect2, varscan2
- CYP4F22 | c.1450G>T p.E484* | Nonsense Mutation (SNP) | VAF 15/30 reads (50%) | catalogued as COSV54107007; called by muse, mutect2, varscan2
- DCHS1 | c.5329C>G p.P1777A | Missense Mutation (SNP) | VAF 24/73 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.6); catalogued as COSV55031651; called by muse, mutect2, varscan2
- EPRS1 | c.2293C>T p.R765C | Missense Mutation (SNP) | VAF 31/90 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.672); catalogued as rs200004369, COSV65097456; called by muse, mutect2, varscan2
- KLK13 | c.172C>T p.R58W | Missense Mutation (SNP) | VAF 25/110 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.894); catalogued as rs200725984; called by muse, mutect2, varscan2
- LRRN3 | c.1815dup p.C606Mfs*12 | Frame Shift Ins (INS) | VAF 8/26 reads (31%) | catalogued as rs747411092; called by mutect2, varscan2
- MYH10 | c.344A>C p.Y115S | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52596182; called by muse, mutect2
- PTPRO | c.3442G>A p.A1148T (on ENST00000281171 / NM_030667.3; = p.A1120T on NM_002848.4) | Missense Mutation (SNP) | VAF 50/168 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.774); catalogued as COSV55504640; called by muse, mutect2, varscan2
- RBM27 | c.3019C>T p.R1007C | Missense Mutation (SNP) | VAF 56/130 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs199579077; called by muse, mutect2, varscan2
- RBP3 | c.1216G>A p.E406K | Missense Mutation (SNP) | VAF 6/59 reads (10%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.692); catalogued as rs576373730; called by muse, mutect2
- RCL1 | c.517G>A p.V173M | Missense Mutation (SNP) | VAF 17/33 reads (52%) | SIFT deleterious (0.01); PolyPhen benign (0.158); catalogued as rs1292770621, COSV67754656; called by muse, mutect2, varscan2
- RNASE7 | c.365A>G p.K122R | Missense Mutation (SNP) | VAF 18/179 reads (10%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.446); catalogued as COSV53876785; called by muse, mutect2
- RP1 | c.1646T>C p.V549A | Missense Mutation (SNP) | VAF 19/57 reads (33%) | SIFT tolerated (0.19); PolyPhen benign (0.028); catalogued as rs1287921799, COSV55111788; called by muse, mutect2, varscan2
- RRNAD1 | c.898C>T p.Q300* | Nonsense Mutation (SNP) | VAF 8/54 reads (15%) | catalogued as COSV63928719; called by muse, mutect2, varscan2
- SF3A1 | c.1414C>T p.R472W | Missense Mutation (SNP) | VAF 73/174 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV53167577; called by muse, mutect2, varscan2
- SHANK2 | c.5015G>A p.R1672Q | Missense Mutation (SNP) | VAF 11/69 reads (16%) | SIFT tolerated (0.11); PolyPhen benign (0.144); catalogued as rs782788809, COSV53588319, COSV99576081; called by muse, mutect2, varscan2
- SUGP1 | c.19A>T p.N7Y | Missense Mutation (SNP) | VAF 30/121 reads (25%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.365); catalogued as rs753871140, COSV53233906; called by muse, mutect2, varscan2
- TMEM63C | c.2050G>A p.A684T | Missense Mutation (SNP) | VAF 34/133 reads (26%) | SIFT tolerated (0.07); PolyPhen benign (0.001); catalogued as rs763988884, COSV53601774; called by muse, mutect2, varscan2
- TULP2 | c.1186G>A p.V396I | Missense Mutation (SNP) | VAF 9/55 reads (16%) | SIFT tolerated (0.2); PolyPhen benign (0.046); catalogued as rs774077208, COSV55476995; called by muse, mutect2, varscan2
- VWA3A | c.1181C>A p.A394D | Missense Mutation (SNP) | VAF 5/72 reads (7%) | SIFT tolerated (0.28); PolyPhen benign (0.001); catalogued as COSV55388546; called by muse, mutect2
- ZFHX4 | c.167G>A p.R56H | Missense Mutation (SNP) | VAF 10/89 reads (11%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.007); catalogued as rs192355194, COSV50556068, COSV99070789; called by muse, mutect2, varscan2
- ZMYM3 | c.2923C>T p.R975* | Nonsense Mutation (SNP) | VAF 10/20 reads (50%) | catalogued as COSV58736509; called by muse, mutect2, varscan2
- ZNF35 | c.823C>A p.Q275K | Missense Mutation (SNP) | VAF 5/67 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.81); catalogued as rs778930777, COSV56075767, COSV56075981; called by muse, mutect2
- BCAT2 | c.1080C>T p.P360= | Silent (SNP) | VAF 34/118 reads (29%) | catalogued as COSV60271888; called by muse, mutect2, varscan2
- CFAP20 | c.435C>G p.G145= | Silent (SNP) | VAF 60/167 reads (36%) | catalogued as COSV52630569; called by muse, mutect2, varscan2
- CSMD1 | c.3990C>T p.H1330= (on ENST00000520002; = p.H1329= on NM_033225.6) | Silent (SNP) | VAF 4/38 reads (11%) | catalogued as rs1294227986, COSV59290476; called by muse, mutect2
- DHTKD1 | c.636C>T p.S212= | Silent (SNP) | VAF 19/52 reads (37%) | catalogued as rs772308172, COSV53802060; called by muse, mutect2, varscan2
- HSF4 | c.327C>G p.G109= | Silent (SNP) | VAF 6/49 reads (12%) | catalogued as rs766350771, COSV50456681, COSV50457400, COSV99263615; called by muse, mutect2, varscan2
- POLR3B | c.2043G>A p.P681= | Silent (SNP) | VAF 15/46 reads (33%) | catalogued as rs372517855; called by muse, mutect2, varscan2
- PTGFRN | c.300C>T p.D100= | Silent (SNP) | VAF 9/51 reads (18%) | catalogued as rs772638079, COSV67797940; called by mutect2, varscan2
- RALYL | c.237C>G p.V79= | Silent (SNP) | VAF 4/46 reads (9%) | catalogued as COSV72818071; called by muse, mutect2
- ST18 | c.1170G>C p.S390= | Silent (SNP) | VAF 10/93 reads (11%) | catalogued as COSV52486527; called by muse, mutect2, varscan2
- TENM4 | c.6171C>T p.Y2057= | Silent (SNP) | VAF 4/42 reads (10%) | catalogued as rs955424965, COSV53611077; called by muse, mutect2
- KCNU1 | c.2010-17168G>A | Intron (SNP) | VAF 4/17 reads (24%) | catalogued as rs1264156052; called by muse, mutect2, varscan2
